Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4789, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4789-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

with right 3.8 cm renal mass.

Specimens Submitted:

1: SP: Kidney, right; partial nephrectomy

DIAGNOSIS:

1. SP: Kidney, right; partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 3.4 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Small vessel angiolymphatic invasion also not identified.

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Focal hyalinizing glomerulosclerosis and mild arteriosclerosis

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor $\leq$ 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
[REDACTED]

1). The specimen is received fresh for frozen section consultation, labeled "Right renal mass" and consists of a partial nephrectomy measuring 4.5 x 3.7 x 2.9 cm. The resected margin is pink brown, rough, and grossly unremarkable; and has been inked black. The capsular surface is smooth pink-tan with attached adipose tissue, and has been inked blue. The specimen is sectioned to reveal a centrally located fairly well circumscribed partially cystic and partially subcapsular tumor nodule measuring 3.4 x 2.5 x 2.7 cm, which is located 0.1 cm from the nearest resected margin. On cut section, the solid portion of the nodule consists of yellow homogenous and focally hemorrhagic soft tissue, and the cystic portion is multilocular, with smooth white tan fibrous septa are noted. The renal capsule and perinephric fat appear grossly uninvolved. The remaining renal parenchyma is pink brown and grossly unremarkable. Representative sections of the specimen are submitted for frozen section consultation, to TPS and for permanent section, and a photograph of the cut sections of the nodule has been taken.

Summary of sections:

FSC -- frozen section control

RST -representative sections tumor with margin and capsule

Summary of Sections:

Part 1: SP: Kidney, right; partial nephrectomy [REDACTED]

Block	Sect. Site	PCs
1	fsc	1
5	rst	5

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM, MARGIN NEGATIVE. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- [REDACTED]

Source: NCI Genomic Data Commons file c616eb1d-32d0-4a33-9221-ee60daf2cf12 (TCGA-BP-4789.FC4372A9-EA9B-42BE-B7B9-9CF2D0192520.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).